Gene-level copy-number profile of tumor specimen TCGA-HT-7477-01B from TCGA case TCGA-HT-7477, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 62.8 years (22,948 days).
Specimen TCGA-HT-7477-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.f7961b47-d971-4100-8212-64d812a6276b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HT-7477-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6c7739bc-a4f5-4452-aa89-19edba91c8b7

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 62; copy number 1: 1,917; copy number 2: 8,152; copy number 3: 15,857; copy number 4: 24,892; copy number 5: 4,686; copy number 6: 1,350; copy number 7: 1,167; copy number 8: 569; copy number 9: 454; copy number 10: 194; copy number 11: 362; copy number 12: 14; copy number 14: 26; copy number 15: 37; copy number 20: 52; copy number 23: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HT-7477-01B-11D-A288-01): tumor purity 0.74, ploidy 3.7, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 62 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:170,226,535–173,041,559, 18 genes (within-gene range 0–2): LINC01612, LINC02512, AC074255.1, HSP90AA6P, LINC02382, AC097486.1, RNU6ATAC13P, AC034159.2, LINC02431, AC034159.1, AC092639.1, MIR6082, LINC02504, AC074254.2, LINC02174, AC074254.1, GALNTL6, AC108064.1.
- chr9:21,802,636–26,805,862, 44 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,157 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:241,453,751–241,519,755, 2 genes, copy number 9: AL359764.3, FH.
- chr2:61,888,724–62,147,247, 1 gene, copy number 9 (within-gene range 2–9): COMMD1.
- chr2:62,069,447–62,350,739, 7 genes, copy number 9: AC018462.1, RPSAP26, AC018462.2, B3GNT2, MIR5192, RN7SL51P, AC093159.2.
- chr2:142,854,095–142,855,998, 1 gene, copy number 9: RRN3P4.
- chr2:183,997,372–184,599,008, 5 genes, copy number 9: AC093639.2, AC096555.1, AC020584.1, MIR548AE1, AC096667.1.
- chr3:22,670,201–22,670,711, 1 gene, copy number 12: AC092421.1.
- chr3:23,389,661–23,389,909, 1 gene, copy number 10: AC121251.1.
- chr3:24,117,153–24,681,711, 7 genes, copy number 10 (within-gene range 3–10): THRB, RPL31P20, THRB-IT1, THRB-AS1, AC012087.2, AC012087.1, EIF3KP2.
- chr3:29,526,251–29,797,825, 2 genes, copy number 10 (within-gene range 4–10): RBMS3-AS2, MTND4LP9.
- chr3:30,292,548–30,305,037, 3 genes, copy number 10: AC025614.2, AC025614.1, U3.
- chr3:169,709,295–169,720,293, 2 genes, copy number 10: SDHDP3, RNU6-637P.
- chr3:178,419,201–178,457,309, 2 genes, copy number 10 (within-gene range 2–10): LINC01014, RNA5SP148.
- chr4:51,843,000–59,075,256, 133 genes, copy number 14–23 (broad region; genes not listed).
- chr7:29,988,600–30,179,014, 11 genes, copy number 11 (within-gene range 3–11): FKBP14-AS1, FKBP14, PLEKHA8, AC007285.1, AC007036.4, AC007036.5, MTURN, AC007036.2, AC007036.3, RPS27P16, AC007036.1.
- chr8:56,211,686–69,104,242, 185 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr8:76,162,119–88,328,025, 176 genes, copy number 9–12 (within-gene range 8–12) (broad region; genes not listed).
- chr8:103,500,696–104,256,094, 1 gene, copy number 11 (within-gene range 8–11): RIMS2.
- chr8:103,768,281–145,066,685, 600 genes, copy number 9–12 (broad region; genes not listed).
- chr9:14,921,013–15,146,401, 1 gene, copy number 9 (within-gene range 8–9): CLCN3P1.
- chr9:15,055,057–16,410,990, 15 genes, copy number 9: PSIP1P1, RNU6-559P, TTC39B, RPL7P33, SNAPC3, RNU6-319P, PSIP1, AL513423.1, RN7SL98P, FTH1P12, RNU6-246P, CCDC171, HMGN2P16, RNU6-14P, C9orf92.
- chr9:16,473,188–16,476,237, 1 gene, copy number 9: AL449983.1.

Autosomal genes at a single copy (total copy number 1): 277. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
